MMRF case MMRF_1250 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d97a54aa-d2a7-4f96-86c3-031305b415c4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.2 years (21,614 days); ISS stage: I; Days to last known disease status: 1,524 days (4.2 years); Days to last follow up: 1,524 days (4.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 298 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 33 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days; Days to treatment end: 298 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,524.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.149 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.3 mg/dL; Immunoglobulin G 35.9 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 3.62 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 9.3 g/dL; Glucose 5.45 mmol/L.
- Day 53 (ECOG 0): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.799 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.1 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 4.33 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 3.47 mmol/L.
- Day 151 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.837 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.71 mg/dL; Immunoglobulin G 14.2 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.34 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 219 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.227 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Hemoglobin 8.43 mmol/L; Leukocytes 3.62 ×10⁹/L; Absolute Neutrophil 2.42 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 337 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.72 mg/dL; Immunoglobulin G 17.9 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.15 ×10⁹/L; Absolute Neutrophil 1.97 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 6.55 mmol/L.
- Day 437 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.24 mg/dL; Hemoglobin 8.37 mmol/L; Leukocytes 3.63 ×10⁹/L; Absolute Neutrophil 1.83 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 4.9 mmol/L.
- Day 521 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.62 mg/dL; Hemoglobin 7.94 mmol/L; Leukocytes 3.33 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.39 mmol/L.
- Day 605 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.32 mg/dL; Immunoglobulin G 18.6 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.52 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 5.01 mmol/L.
- Day 719 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.5 mg/dL; Immunoglobulin G 20.1 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.41 ×10⁹/L; Absolute Neutrophil 1.65 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 4.51 mmol/L.
- Day 803 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.66 mg/dL; Immunoglobulin G 18.9 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.32 ×10⁹/L; Absolute Neutrophil 1.71 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.34 mmol/L.
- Day 880 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7 mg/dL; Immunoglobulin G 18.3 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.09 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.83 mmol/L.
- Day 962 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.34 mg/dL; Immunoglobulin G 20.6 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.38 ×10⁹/L; Absolute Neutrophil 1.23 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 7.54 mmol/L.
- Day 1,040 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.92 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 2.92 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 7.48 mmol/L.
- Day 1,144 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.72 mg/dL; Hemoglobin 7.75 mmol/L; Leukocytes 2.68 ×10⁹/L; Absolute Neutrophil 1.27 ×10⁹/L; Platelets 165 ×10⁹/L.
- Day 1,255 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Hemoglobin 8.31 mmol/L; Leukocytes 4.88 ×10⁹/L; Absolute Neutrophil 3.64 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 1,331 (ECOG 2): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Hemoglobin 9.11 mmol/L; Leukocytes 4.25 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 1,424 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.03 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 3.08 ×10⁹/L; Absolute Neutrophil 1.82 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -13: Weight: 72 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1250_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1250_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
